Somatic mutation profile of tumor specimen TCGA-YF-AA3L-01A (aliquot TCGA-YF-AA3L-01A-11D-A38G-08) from TCGA case TCGA-YF-AA3L, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 47.3 years (17,268 days).
Specimen TCGA-YF-AA3L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6be7d416-1308-4e1d-8e31-40a8c8db3961.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YF-AA3L-10A (Blood Derived Normal), aliquot TCGA-YF-AA3L-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a170b2f-57de-44ba-ba85-56c17851fd62

The open-access MAF lists 338 somatic variants for this specimen: 253 protein-altering or splice-affecting, 72 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 72, Nonsense Mutation 15, Frame Shift Del 12, Intron 6, Splice Site 6, RNA 4, 3'UTR 2, Splice Region 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABHD13 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV65535167; called by muse, mutect2, varscan2
- ACAD8 | c.119G>C p.G40A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55541140; called by muse, mutect2, varscan2
- ACAN | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs766293702, COSV61356528; called by muse, mutect2, varscan2
- ADA | c.362A>T p.E121V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs748035221, COSV65740294; called by muse, mutect2, varscan2
- ADAM29 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 53/244 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.713); catalogued as rs1163057949, COSV63665226; called by muse, mutect2, varscan2
- ADAMTSL3 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 11/50 reads (22%) | catalogued as COSV54446085, COSV99716519; called by muse, mutect2, varscan2
- ADD2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs782645890, COSV52464399; called by muse, mutect2, varscan2
- AFP | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV56925807; called by muse, mutect2, varscan2
- AKNAD1 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV62197051, COSV62200115; called by muse, mutect2, varscan2
- AMOTL1 | c.244A>C p.I82L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100133605; called by muse, mutect2
- ANK2 | c.1259A>G p.Y420C | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768099021, COSV52170892; called by muse, mutect2
- ANKRD30A | c.1919C>G p.S640C (on ENST00000611781; = p.S584C on NM_052997.2) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as COSV64614151, COSV64614928; called by muse, mutect2, varscan2
- ARAP3 | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775720602, COSV53351973; called by muse, mutect2, varscan2
- ARVCF | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs375457783; called by muse, mutect2, varscan2
- ASAP1 | c.3124G>C p.E1042Q | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV63050952; called by muse, mutect2, varscan2
- ATAD3B | c.622G>T p.V208L (on ENST00000308647; = p.V314L on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV58021745; called by muse, mutect2, varscan2
- ATAD5 | c.3001G>A p.V1001I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs566790418, COSV58976148; called by muse, mutect2
- ATP2B2 | c.3329G>A p.R1110Q (on ENST00000352432; = p.R1076Q on NM_001683.5) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.991); catalogued as COSV59500585; called by muse, mutect2, varscan2
- ATP5PB | c.766A>G p.M256V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV63854132; called by muse, mutect2, varscan2
- BEST4 | c.191A>C p.Q64P | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV64734119; called by muse, mutect2, varscan2
- BIRC6 | c.7240G>C p.D2414H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70202049; called by muse, mutect2, varscan2
- C15orf39 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV100641398, COSV62297188; called by muse, mutect2, varscan2
- CA10 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as rs1231495184, COSV53357489; called by muse, mutect2, varscan2
- CASK | c.1806+2T>C p.X602_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV59370229; called by muse, mutect2, varscan2
- CATSPERB | c.891G>C p.W297C | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56429219; called by muse, mutect2, varscan2
- CCDC47 | c.735+1G>C p.X245_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV56723531; called by muse, mutect2, varscan2
- CCDC63 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as rs369178253; called by muse, mutect2, varscan2
- CCDC73 | c.1634T>A p.I545K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58800808; called by muse, mutect2, varscan2
- CCNJ | c.1072C>A p.Q358K | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.931); catalogued as COSV56443555; called by muse, mutect2, varscan2
- CCSER1 | c.1255A>T p.I419L | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.51); catalogued as rs202091224, COSV61443413; called by muse, mutect2, varscan2
- CD101 | c.2525C>A p.S842* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV99868979; called by muse, mutect2
- CD101 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as rs1337687739, COSV56716700; called by muse, mutect2
- CDCA4 | c.40G>C p.E14Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as COSV60315163, COSV60315663; called by muse, mutect2, varscan2
- CDH26 | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.333); catalogued as COSV54849365; called by muse, mutect2, varscan2
- CDHR2 | c.3625C>A p.P1209T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56141149; called by muse, mutect2, varscan2
- CFH | c.1340C>T p.T447I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.867); catalogued as rs369387485, COSV100808588; called by muse, mutect2
- CHD1L | c.1502T>C p.L501P | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV63614575; called by muse, mutect2
- CHD8 | c.4302A>T p.R1434S (on ENST00000646647 / NM_001170629.2; = p.R1155S on NM_020920.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV63219336; called by muse, mutect2, varscan2
- CILP | c.648_649del p.C216* | Nonsense Mutation (DEL) | VAF 10/39 reads (26%) | catalogued as rs764627822; called by pindel, varscan2
- CLEC14A | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60563191, COSV99046217; called by muse, mutect2, varscan2
- CMKLR1 | c.475G>C p.A159P (on ENST00000312143 / NM_001142344.2; = p.A157P on NM_004072.3) | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV56439546; called by muse, mutect2, varscan2
- CNKSR2 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54260268; called by muse, mutect2, varscan2
- CNTN1 | c.1430A>T p.N477I | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV61641780; called by muse, mutect2, varscan2
- COL12A1 | c.7840C>T p.P2614S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as rs772870762, COSV59397992; called by muse, mutect2, varscan2
- COL24A1 | c.4250G>C p.G1417A | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65308901; called by muse, mutect2, varscan2
- COL25A1 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67652739; called by muse, mutect2, varscan2
- COL2A1 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV61531992, COSV61534702; called by muse, mutect2
- COL5A2 | c.1285G>T p.G429C | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411227; called by muse, mutect2, varscan2
- COL6A6 | c.1882G>C p.D628H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62029442; called by muse, mutect2, varscan2
- COL8A1 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.954); catalogued as COSV53737257; called by muse, mutect2, varscan2
- CPA5 | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs781915251, COSV62570053; called by muse, mutect2, varscan2
- CSRP2 | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV60702946; called by muse, mutect2, varscan2
- CTH | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs139166171; called by muse, mutect2, varscan2
- CTLA4 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55592599; called by muse, mutect2, varscan2
- CUX2 | c.3724G>A p.G1242R | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs201097767; called by muse, mutect2, varscan2
- CXCL10 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV60661132; called by muse, mutect2
- DCAF12L1 | c.924T>A p.D308E | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64422115; called by muse, mutect2, varscan2
- DDR2 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV63372169; called by muse, mutect2, varscan2
- DMTF1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100487195; called by muse, mutect2, varscan2
- DNAH11 | c.4154G>A p.G1385D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs774318097, COSV100176369; called by muse, mutect2
- DNAH9 | c.5812C>A p.Q1938K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV52358452; called by muse, mutect2, varscan2
- DRP2 | c.961T>A p.W321R | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65810856; called by muse, mutect2, varscan2
- EPHX3 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs142332224; called by mutect2, varscan2
- ERCC6L | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.29); catalogued as COSV57821306; called by muse, mutect2, varscan2
- ETV1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV54145680; called by muse, mutect2, varscan2
- F8 | c.6390G>T p.K2130N | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV64275341; called by muse, mutect2, varscan2
- FAM47B | c.952A>T p.S318C | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV61455165; called by muse, mutect2, varscan2
- FBXO46 | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.144); catalogued as rs1417447817, COSV58349069; called by muse, mutect2, varscan2
- FKBP9 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as COSV54232439; called by muse, mutect2, varscan2
- FLNC | c.4963G>A p.G1655S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV57958685; called by muse, mutect2, varscan2
- FN1 | c.3463G>T p.V1155F | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60556912; called by muse, mutect2, varscan2
- GABRA1 | c.620T>G p.V207G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV50109499; called by muse, mutect2, varscan2
- GAD2 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 13/64 reads (20%) | catalogued as COSV99392341; called by muse, mutect2, varscan2
- GALNTL5 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67180506; called by muse, mutect2, varscan2
- GATB | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56131488; called by muse, mutect2, varscan2
- GFM1 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 19/92 reads (21%) | catalogued as COSV51836337, COSV99962625; called by muse, mutect2, varscan2
- GFPT2 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV53809742; called by muse, mutect2, varscan2
- GIMAP8 | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV56232461; called by muse, mutect2, varscan2
- GIPR | c.543G>A p.M181I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54424768; called by muse, mutect2, varscan2
- GPC4 | c.712-1G>T p.X238_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | catalogued as COSV63698560; called by muse, mutect2, varscan2
- GPKOW | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99332445; called by muse, mutect2, varscan2
- GRIA3 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV52068640; called by muse, mutect2, varscan2
- GRIK1 | c.1499C>A p.P500H | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV58723439; called by muse, mutect2, varscan2
- GRIK2 | c.1033T>A p.L345M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59748269; called by muse, mutect2, varscan2
- GRIK4 | c.204C>G p.I68M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV70804022, COSV70806030; called by muse, mutect2, varscan2
- GTF2A1 | c.890A>G p.E297G | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV53337576, COSV99993492; called by muse, mutect2, varscan2
- GYG2 | c.1271A>C p.E424A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs145468285, COSV100088613; called by mutect2, varscan2
- H1-8 | c.806A>G p.K269R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100138873; called by muse, mutect2
- HARBI1 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56320432; called by muse, mutect2, varscan2
- HELLS | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1480111803, COSV99491651; called by muse, mutect2
- HIRA | c.2596C>T p.Q866* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV99599808; called by muse, mutect2
- HOXC13 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs761646324, COSV54499221; called by muse, mutect2, varscan2
- HSPA12A | c.1957A>G p.I653V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.365); catalogued as rs1554877306, COSV65022924; called by muse, mutect2, varscan2
- HTR1A | c.724C>A p.H242N | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV60501623; called by muse, mutect2, varscan2
- IFIT3 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs974974070, COSV51079570; called by muse, mutect2, varscan2
- IFRD1 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.741); catalogued as rs1230781853, COSV50044520; called by mutect2, varscan2
- IFT122 | c.1265T>G p.M422R (on ENST00000348417 / NM_052989.3; = p.M363R on NM_018262.4) | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV56204864; called by muse, mutect2, varscan2
- IGHV1-46 | c.49G>T p.A17S | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs781888621; called by muse, mutect2, varscan2
- IGLV2-8 | c.176A>G p.Q59R | Missense Mutation (SNP) | VAF 90/304 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.076); catalogued as rs1253698209; called by muse, mutect2, varscan2
- INTS8 | c.862-1G>C p.X288_splice | Splice Site (SNP) | VAF 38/163 reads (23%) | catalogued as COSV58251574; called by muse, mutect2, varscan2
- INTS8 | c.1496A>G p.Y499C | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs144127105; called by muse, mutect2, varscan2
- KCNA5 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52903752, COSV99363529; called by muse, mutect2
- KCNH5 | c.2345T>C p.M782T | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.012); catalogued as COSV59765429; called by muse, mutect2, varscan2
- KCNK5 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV63989090; called by muse, mutect2, varscan2
- KDR | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 27/165 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs371800274; called by muse, mutect2, varscan2
- KIAA1109 | c.9469C>G p.L3157V | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV52680761; called by muse, mutect2, varscan2
- KIF21B | c.521T>A p.I174N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59760759; called by muse, mutect2, varscan2
- KIF2B | c.1676A>T p.H559L | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV52132528; called by muse, mutect2, varscan2
- KIF4B | c.3152C>G p.S1051C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV70530168; called by muse, mutect2, varscan2
- KIFAP3 | c.736A>G p.K246E | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV63035131; called by muse, mutect2, varscan2
- KNDC1 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 16/37 reads (43%) | catalogued as rs1195388230, COSV100463050; called by muse, mutect2, varscan2
- KRT222 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67498542; called by muse, mutect2, varscan2
- LAD1 | c.1493C>G p.S498C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs767205434, COSV66212801; called by muse, mutect2, varscan2
- LARGE1 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV100504785, COSV61665244; called by muse, mutect2, varscan2
- LCP2 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1215778118, COSV99251879; called by muse, mutect2
- LPA | c.4592C>T p.P1531L | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60304671; called by muse, mutect2, varscan2
- LRFN3 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776754660, COSV55818161; called by muse, mutect2, varscan2
- LRFN5 | c.1694A>G p.K565R | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV53264080; called by muse, mutect2, varscan2
- LRRC61 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV99784518; called by muse, mutect2, varscan2
- LRRIQ1 | c.2140A>T p.K714* | Nonsense Mutation (SNP) | VAF 78/344 reads (23%) | catalogued as COSV101279276, COSV101280818; called by muse, mutect2, varscan2
- LRTM1 | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs970989074, COSV55554343; called by muse, mutect2, varscan2
- MAGEB10 | c.601A>G p.T201A | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV63311794; called by muse, mutect2, varscan2
- MDM1 | c.1763G>A p.G588D | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57447369; called by muse, mutect2, varscan2
- MDN1 | c.15942G>C p.Q5314H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV65524307; called by muse, mutect2, varscan2
- MED12 | c.967C>G p.Q323E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.597); catalogued as COSV61332513, COSV61345235; called by muse, mutect2, varscan2
- MET | c.2422C>A p.Q808K | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.253); catalogued as COSV59263921, COSV59270758; called by muse, mutect2, varscan2
- MIA2 | c.1553del p.P518Hfs*65 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | catalogued as COSV54497929; called by mutect2, pindel, varscan2
- MKRN2 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); catalogued as rs760980014, COSV50104307, COSV50105797; called by muse, varscan2
- MLXIPL | c.1900C>A p.Q634K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as COSV57668977; called by muse, mutect2, varscan2
- MOCOS | c.488T>C p.M163T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1290084024, COSV54344951; called by mutect2, varscan2
- MSC | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372185110, COSV57697024; called by muse, mutect2, varscan2
- MSL3 | c.1058G>A p.R353H (on ENST00000312196 / NM_078629.4; = p.R187H on NM_006800.4) | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV56491941, COSV56494290; called by muse, mutect2, varscan2
- MUC16 | c.38057C>T p.S12686F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as rs764893229, COSV67476724; called by muse, mutect2, varscan2
- MUC4 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs769746505, COSV62163527; called by muse, mutect2, varscan2
- MYEF2 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1390725698, COSV51049487; called by muse, mutect2, varscan2
- MYH2 | c.3098T>G p.L1033R | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55441647; called by muse, mutect2, varscan2
- MYO1D | c.3013G>T p.G1005W | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100531886, COSV57831034; called by muse, mutect2
- NAA35 | c.1982A>T p.K661M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV64485381; called by muse, mutect2, varscan2
- NGFR | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs1187087152, COSV99412612; called by muse, mutect2, varscan2
- NPAT | c.3050C>T p.S1017L | Missense Mutation (SNP) | VAF 66/97 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV53719158; called by muse, mutect2, varscan2
- NPHS1 | c.2711T>A p.L904Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100799549; called by muse, mutect2
- NRAP | c.1616C>A p.A539D (on ENST00000359988 / NM_001322945.2; = p.A504D on NM_006175.4) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1282734451, COSV63488865; called by muse, mutect2, varscan2
- NUP153 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV50448934, COSV50453191; called by muse, mutect2, varscan2
- OR5T1 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.076); catalogued as rs1376780712, COSV57303483; called by muse, mutect2, varscan2
- PALB2 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as rs587778587, CM156713, COSV55163483; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PCDH11X | c.670G>C p.G224R | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53439044, COSV53464634; called by muse, mutect2, varscan2
- PCDHB16 | c.1364C>A p.S455Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as COSV53365169; called by muse, mutect2, varscan2
- PDK4 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.441); catalogued as rs1298369398, COSV50011441; called by muse, mutect2, varscan2
- PEG3 | c.3079G>C p.E1027Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV55638419; called by muse, mutect2, varscan2
- PFKFB1 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 10/63 reads (16%) | PolyPhen possibly damaging (0.503); catalogued as rs759599398, COSV66628222; called by muse, mutect2, varscan2
- PGAM5 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV58202445; called by muse, mutect2, varscan2
- PI16 | c.640A>T p.T214S | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV65448368; called by muse, mutect2, varscan2
- PLPPR5 | c.60G>C p.M20I | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV54175064, COSV54175695; called by muse, mutect2, varscan2
- PLXNA4 | c.2739G>T p.Q913H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58102701, COSV58139162; called by muse, mutect2, varscan2
- PLXNA4 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV58116729; called by mutect2, varscan2
- POLR1E | c.1291A>G p.M431V (on ENST00000377792 / NM_001282766.1; = p.M369V on NM_022490.4) | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV66772477; called by muse, mutect2, varscan2
- POT1 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1554426928, COSV62931832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R12A | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54110637; called by muse, mutect2, varscan2
- PRC1 | c.1326G>C p.E442D | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV62695877; called by muse, mutect2, varscan2
- PRDM13 | c.1448A>G p.K483R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.409); catalogued as rs1308386468, COSV65030221; called by muse, mutect2, varscan2
- PRKCG | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV54729761; called by muse, mutect2, varscan2
- PRPF8 | c.4225G>C p.E1409Q | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV59264826; called by muse, mutect2, varscan2
- PSG4 | c.801G>C p.K267N | Missense Mutation (SNP) | VAF 60/321 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV54937236; called by muse, mutect2, varscan2
- PSMD8 | c.801C>G p.I267M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as rs1256369298, COSV99287273; called by muse, mutect2
- PSMD9 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758694222, COSV55839960; called by muse, mutect2, varscan2
- PTCHD1 | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.641); catalogued as COSV65061465; called by muse, mutect2, varscan2
- PURB | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated, low confidence (0.72); PolyPhen possibly damaging (0.696); catalogued as COSV101194872; called by muse, mutect2
- QSOX1 | c.1887G>C p.Q629H | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.359); catalogued as COSV62580905; called by muse, mutect2, varscan2
- RBBP7 | c.400C>A p.Q134K | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV66301113; called by muse, varscan2
- RBM33 | c.3488T>G p.I1163R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV62032047; called by muse, mutect2, varscan2
- REG1B | c.371G>T p.W124L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1291858142, COSV59306488; called by muse, mutect2, varscan2
- RNF216 | c.471G>C p.E157D (on ENST00000425013 / NM_207116.3; = p.E214D on NM_207111.4) | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV66291420; called by muse, mutect2
- RP1 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.034); catalogued as COSV55119207; called by muse, mutect2, varscan2
- RREB1 | c.4819A>G p.N1607D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as rs767996104, COSV58560488; called by muse, mutect2, varscan2
- RRH | c.881A>C p.Y294S | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58491976; called by muse, mutect2, varscan2
- RTL8C | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV99924257; called by muse, mutect2
- RUSC1 | c.2270G>A p.R757H (on ENST00000368352 / NM_001105203.2; = p.R288H on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs768034492, COSV52738156; called by muse, mutect2, varscan2
- RYR2 | c.7205G>C p.C2402S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM0910991, COSV63695026; called by muse, mutect2, varscan2
- SDK1 | c.1259G>T p.W420L | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101268637; called by muse, mutect2
- SELP | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV55249955, COSV55254157; called by muse, mutect2, varscan2
- SEMA3D | c.1697C>T p.S566F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV52397469; called by muse, mutect2, varscan2
- SEMA4B | c.2413A>G p.K805E | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1428521080, COSV60174407; called by muse, mutect2, varscan2
- SERPINB3 | c.469+1G>A p.X157_splice | Splice Site (SNP) | VAF 15/39 reads (38%) | catalogued as COSV52192533; called by muse, mutect2, varscan2
- SH3BP4 | c.2129G>C p.R710T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1355517069, COSV60644646; called by muse, mutect2, varscan2
- SHCBP1 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV100317457, COSV57648366; called by muse, mutect2, varscan2
- SIGLEC8 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as rs766696603, COSV58474492; called by muse, mutect2, varscan2
- SIK3 | c.479G>T p.R160L (on ENST00000445177 / NM_001366686.2; = p.R166L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760997905, COSV52617848; called by muse, mutect2, varscan2
- SIKE1 | c.417G>C p.E139D | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as COSV50259044; called by muse, mutect2, varscan2
- SLC13A2 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV58996398; called by muse, mutect2, varscan2
- SLC17A3 | c.386T>C p.L129S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.374); catalogued as rs757564537, COSV57760613; called by muse, mutect2, varscan2
- SLC18B1 | c.932T>C p.L311S | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as COSV51595033; called by muse, mutect2, varscan2
- SLC25A31 | c.794T>C p.L265S | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV55419965; called by muse, mutect2, varscan2
- SLC7A5 | c.371A>T p.Y124F | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV55365282; called by muse, mutect2, varscan2
- SLCO5A1 | c.1652T>A p.L551Q | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52662248; called by muse, mutect2, varscan2
- SLCO5A1 | c.1219A>G p.K407E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV52662262; called by muse, mutect2, varscan2
- SLIRP | c.20G>C p.R7T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1457090032, COSV53173894, COSV53173921, COSV53174466; called by muse, mutect2, varscan2
- SMARCD3 | c.1344G>C p.E448D (on ENST00000262188 / NM_001003801.2; = p.E435D on NM_003078.4) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV50393091; called by muse, mutect2, varscan2
- SMCR8 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as COSV58178790; called by muse, mutect2, varscan2
- SMYD3 | c.907del p.E303Sfs*11 (on ENST00000490107 / NM_001375962.1; = p.E244Sfs*11 on NM_022743.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as rs1231546513; called by mutect2, pindel, varscan2
- SOS1 | c.1792A>G p.I598V | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV67676248; called by muse, mutect2, varscan2
- SOX9 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 72/132 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as rs551719325, CD098478, COSV55423056, COSV55425610; called by muse, mutect2, varscan2
- SRP68 | c.1176C>G p.I392M | Missense Mutation (SNP) | VAF 40/304 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV57163445; called by muse, mutect2, varscan2
- STK32B | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51496896; called by muse, mutect2, varscan2
- SUCO | c.3655C>G p.L1219V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV55261379; called by muse, mutect2
- SYT3 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as rs771656522, COSV58897560; called by muse, mutect2, varscan2
- TENM3 | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.096); catalogued as COSV69312571; called by muse, mutect2
- TENM4 | c.7125G>C p.L2375F | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.348); catalogued as COSV53642819; called by muse, mutect2, varscan2
- TNC | c.1621C>A p.R541S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV60786725; called by muse, mutect2, varscan2
- TNS1 | c.741G>A p.L247= | Splice Region (SNP) | VAF 22/62 reads (35%) | catalogued as COSV50719554; called by muse, mutect2, varscan2
- TOP3A | c.1669A>T p.K557* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV100328860; called by muse, mutect2, varscan2
- TRANK1 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs745527401, COSV57151749, COSV57155023; called by muse, mutect2, varscan2
- TRPC3 | c.2624-2A>T p.X875_splice (on ENST00000379645 / NM_001366479.2; = p.X802_splice on NM_003305.2) | Splice Site (SNP) | VAF 13/111 reads (12%) | catalogued as COSV53377441; called by muse, mutect2, varscan2
- TRPV2 | c.1397T>C p.I466T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs1305047105, COSV100641184, COSV58429128; called by muse, mutect2, varscan2
- TSEN2 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as COSV53189591; called by muse, mutect2, varscan2
- TSPYL6 | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV57816852; called by muse, mutect2, varscan2
- TTC29 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV100283030; called by muse, mutect2
- TWNK | c.1724G>C p.G575A | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54550931; called by muse, mutect2, varscan2
- UAP1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54851719; called by muse, mutect2, varscan2
- UBR5 | c.2021A>G p.D674G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55291988; called by muse, mutect2, varscan2
- UGT8 | c.1097A>G p.E366G | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1237101519, COSV60418961; called by muse, mutect2, varscan2
- USP49 | c.1664G>T p.R555I | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51898768; called by muse, mutect2, varscan2
- VNN1 | c.1046G>C p.G349A | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV63390276; called by muse, mutect2, varscan2
- VPS16 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV100988230; called by muse, mutect2
- WDR62 | c.3557A>G p.D1186G | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV54336585; called by muse, mutect2, varscan2
- XYLT1 | c.1596C>G p.F532L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV54488697; called by muse, mutect2, varscan2
- YTHDC2 | c.3217G>T p.A1073S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs1259710313, COSV50745332; called by muse, mutect2, varscan2
- YTHDC2 | c.3218C>G p.A1073G | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV50745385; called by muse, mutect2, varscan2
- ZBTB12 | c.127_130del p.K43Ffs*21 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as COSV64993973; called by mutect2, pindel, varscan2
- ZBTB21 | c.2698G>C p.A900P | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60404751; called by muse, mutect2, varscan2
- ZC3H12B | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59046926; called by muse, mutect2, varscan2
- ZCWPW2 | c.443G>T p.R148I | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV67497639, COSV67499741; called by muse, mutect2, varscan2
- ZNF33B | c.2321A>G p.E774G | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV63942840; called by muse, mutect2, varscan2
- ZNF479 | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV58640315; called by muse, mutect2, varscan2
- ZNF502 | c.1446T>G p.H482Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs867676959, COSV56074064; called by muse, mutect2, varscan2
- ZNF521 | c.3011T>C p.L1004S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV64128702; called by muse, mutect2, varscan2
- ZNF546 | c.2390_2391del p.R797Nfs*5 | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs774673097; called by mutect2, pindel, varscan2
- ZNF567 | c.756A>C p.K252N (on ENST00000536254 / NM_001322913.1; = p.K221N on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100658590, COSV62444016, COSV62445934; called by muse, mutect2, varscan2
- ZNF608 | c.3461C>G p.S1154* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100100794; called by muse, mutect2, varscan2
- ZNF611 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 70/317 reads (22%) | catalogued as COSV100159927, COSV60542024; called by muse, mutect2, varscan2
- ZNF750 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 144/269 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV53961127; called by muse, mutect2, varscan2
- ZNF774 | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV62980437; called by muse, mutect2, varscan2
- ZNF80 | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV57361563; called by muse, mutect2, varscan2
- AKAP9 | c.2818_2819del p.E940Tfs*6 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- ALMS1 | c.706del p.Q236Kfs*14 | Frame Shift Del (DEL) | VAF 62/190 reads (33%) | called by mutect2, pindel, varscan2
- APAF1 | c.2975del p.N992Tfs*56 (on ENST00000551964 / NM_181861.2; = p.N938Tfs*56 on NM_001160.3) | Frame Shift Del (DEL) | VAF 26/69 reads (38%) | called by mutect2, pindel, varscan2
- DHX9 | c.2613del p.C872Vfs*45 | Frame Shift Del (DEL) | VAF 17/57 reads (30%) | called by mutect2, pindel, varscan2
- DUSP7 | c.542_543del p.E181Vfs*3 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by pindel, varscan2
- NAA25 | c.259_260del p.I87Pfs*16 | Frame Shift Del (DEL) | VAF 23/114 reads (20%) | called by mutect2, pindel, varscan2
- SHOC1 | c.1957_1958del p.E653Nfs*16 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by pindel, varscan2
- STEAP2 | c.1468dup p.M490Nfs*37 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- TAF1L | c.1312del p.E438Rfs*27 | Frame Shift Del (DEL) | VAF 44/158 reads (28%) | called by mutect2, pindel, varscan2
- TRGV3 | c.263C>G p.T88S | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- AC126283.2 | c.420A>T p.I140= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV67098933, COSV67099145; called by muse, mutect2, varscan2
- ACACB | c.4113C>T p.A1371= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV58138635; called by muse, mutect2, varscan2
- ACBD4 | c.403A>C p.R135= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV58852508; called by muse, mutect2, varscan2
- ADGRB2 | c.3693G>T p.S1231= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs201162344, COSV57075553; called by muse, mutect2, varscan2
- ARHGAP45 | c.1551G>T p.T517= | Silent (SNP) | VAF 27/119 reads (23%) | catalogued as rs769452353, COSV57433564; called by muse, mutect2, varscan2
- ARHGEF10 | c.2949G>A p.V983= (on ENST00000398564; = p.V958= on NM_014629.4) | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100035560, COSV50645838; called by muse, mutect2, varscan2
- ARID1B | c.3471G>A p.G1157= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV51668461; called by muse, mutect2, varscan2
- ASCC3 | c.5559A>G p.E1853= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV100976161; called by muse, mutect2
- ATP10A | c.1884G>A p.L628= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs1245813563, COSV63519635; called by muse, mutect2, varscan2
- ATP1A3 | c.792G>A p.T264= (on ENST00000545399 / NM_001256214.2; = p.T251= on NM_152296.5) | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs782459932, COSV57491739; ClinVar: likely benign; called by muse, mutect2
- BAZ1A | c.1875G>A p.L625= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1379018952, COSV62410859; called by muse, mutect2, varscan2
- BCORL1 | c.723T>C p.V241= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV54399844; called by muse, mutect2, varscan2
- BDKRB2 | c.579G>A p.L193= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1338049708, COSV60015671, COSV60016922; called by muse, mutect2, varscan2
- CASK | c.552T>C p.H184= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100586775; called by muse, mutect2
- CDYL2 | c.57G>A p.K19= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV73647735; called by muse, mutect2, varscan2
- CNNM2 | c.1359C>T p.L453= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as COSV63995598, COSV63996429; called by muse, mutect2, varscan2
- CNTNAP1 | c.3240G>C p.T1080= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV52851895; called by muse, mutect2, varscan2
- COL6A6 | c.4080C>A p.L1360= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV62029456; called by muse, mutect2, varscan2
- CPSF3 | c.309T>C p.Y103= | Silent (SNP) | VAF 78/176 reads (44%) | catalogued as COSV53010425; called by muse, mutect2, varscan2
- CUL4B | c.369C>T p.D123= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV60689081; called by muse, varscan2
- DKK2 | c.369T>C p.N123= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as COSV53399511; called by muse, mutect2, varscan2
- DNAH11 | c.13209A>G p.K4403= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100176372; called by muse, mutect2
- EFEMP1 | c.1395G>T p.L465= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV62616803; called by muse, mutect2, varscan2
- ELN | c.1470T>C p.G490= | Silent (SNP) | VAF 53/227 reads (23%) | catalogued as rs576324025, COSV52710037; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERBB2 | c.255C>G p.L85= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV54074586; called by muse, mutect2, varscan2
- FCRL6 | c.60G>A p.L20= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as COSV58941684; called by muse, mutect2, varscan2
- FYCO1 | c.801C>T p.V267= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1163017329, COSV56117227; called by muse, mutect2, varscan2
- GCK | c.963C>A p.S321= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs753628968, CD097036, COSV60785778, COSV60787231, COSV60788173; called by muse, mutect2, varscan2
- GDF2 | c.366C>G p.A122= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- GIMAP1 | c.492T>C p.D164= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs1563365593, COSV56188864; called by muse, mutect2, varscan2
- GUCA1A | c.420C>T p.F140= | Silent (SNP) | VAF 39/113 reads (35%) | catalogued as COSV50004543; called by muse, mutect2, varscan2
- GXYLT1 | c.939C>T p.I313= | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV55138749; called by muse, mutect2, varscan2
- HTR1A | c.1038G>T p.T346= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV60500995, COSV60501612; called by muse, mutect2, varscan2
- IGLL1 | c.216C>A p.L72= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV50770097; called by muse, varscan2
- IL12RB2 | c.1452G>A p.L484= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV52024567; called by muse, mutect2, varscan2
- IRF8 | c.723G>A p.L241= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV51898787; called by muse, mutect2
- ITGAE | c.2229A>T p.S743= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV53996207; called by muse, mutect2, varscan2
- ITPR2 | c.6069G>C p.L2023= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV67271713; called by muse, mutect2, varscan2
- KLHL7 | c.1251G>T p.L417= (on ENST00000339077 / NM_001031710.3; = p.L369= on NM_018846.5) | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV59162449; called by muse, mutect2, varscan2
- LRP6 | c.2628G>A p.V876= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV53789865; called by muse, mutect2, varscan2
- MUC17 | c.4527T>C p.P1509= | Silent (SNP) | VAF 138/282 reads (49%) | catalogued as rs753658368, COSV60294042; called by muse, mutect2, varscan2
- MYCBP2 | c.9207A>G p.P3069= (on ENST00000357337; = p.P3107= on NM_015057.5) | Silent (SNP) | VAF 29/91 reads (32%) | catalogued as COSV62027047; called by muse, mutect2, varscan2
- MYOC | c.192G>A p.Q64= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as COSV50674445, COSV50675911; called by muse, mutect2
- MYOM2 | c.519C>A p.L173= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV50729833; called by muse, mutect2, varscan2
- NEU1 | c.663G>T p.G221= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV57667961; called by muse, mutect2, varscan2
- NRP2 | c.708T>A p.S236= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV55930812; called by muse, mutect2, varscan2
- OR51F2 | c.591C>T p.N197= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV59065244; called by muse, mutect2, varscan2
- PCDH1 | c.1506C>T p.N502= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs151258191, COSV54614261; called by muse, mutect2, varscan2
- PCDH19 | c.3240C>T p.S1080= (on ENST00000373034 / NM_001184880.2; = p.S1032= on NM_020766.3) | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs766005861, COSV55266139; called by muse, mutect2, varscan2
- PDS5A | c.2526G>A p.L842= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs975159632, COSV57827731; called by muse, mutect2
- PKHD1L1 | c.8136T>C p.H2712= | Silent (SNP) | VAF 73/164 reads (45%) | catalogued as rs1243027060, COSV65746557; called by muse, mutect2, varscan2
- PLCD3 | c.1224G>A p.R408= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100504466, COSV59561326; called by muse, mutect2, varscan2
- PLEKHA4 | c.522C>T p.P174= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs571371427, COSV54364188; called by muse, mutect2, varscan2
- PRMT9 | c.402C>T p.F134= | Silent (SNP) | VAF 44/184 reads (24%) | catalogued as COSV59360290; called by muse, mutect2, varscan2
- RASGRP4 | c.1830A>T p.T610= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV53039189; called by muse, mutect2, varscan2
- RBM45 | c.354A>G p.E118= | Silent (SNP) | VAF 32/72 reads (44%) | catalogued as COSV53720013; called by muse, mutect2, varscan2
- RYR2 | c.12240C>T p.Y4080= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1335612184, COSV63707617; called by muse, mutect2
- SLC16A14 | c.1116C>T p.V372= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs773699384, COSV54619435; called by muse, mutect2, varscan2
- SLC17A7 | c.1200C>T p.S400= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV55548487; called by muse, mutect2, varscan2
- SLC7A1 | c.213G>C p.L71= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV101060290, COSV66330960; called by muse, mutect2, varscan2
- SOCS3 | c.534G>A p.L178= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs957967092, COSV58270793; called by muse, mutect2, varscan2
- STK32B | c.462G>T p.L154= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as COSV51496905; called by muse, mutect2, varscan2
- STYXL2 | c.1815G>A p.K605= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99608430; called by muse, mutect2
- SYTL2 | c.1203A>G p.V401= | Silent (SNP) | VAF 21/101 reads (21%) | catalogued as COSV60360612; called by muse, mutect2, varscan2
- TEK | c.2010T>C p.I670= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV66230287; called by muse, mutect2, varscan2
- THPO | c.1236G>C p.P412= (on ENST00000649095 / NM_001290003.1; = p.P272= on NM_000460.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 35/156 reads (22%) | catalogued as COSV52616367, COSV52617165; called by muse, mutect2, varscan2
- TNFAIP1 | c.684C>T p.I228= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1555578310, COSV50228580, COSV99134850; called by muse, mutect2, varscan2
- UFL1 | c.87G>A p.E29= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV65150128; called by muse, mutect2, varscan2
- UROC1 | c.1863G>A p.L621= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs1434003386, COSV52035305; called by muse, mutect2, varscan2
- WDR11 | c.660T>A p.G220= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV54790090; called by muse, mutect2, varscan2
- XIRP1 | c.3441C>T p.P1147= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs745587316, COSV61139398, COSV61140227; called by muse, mutect2, varscan2
- ZNF608 | c.1125G>T p.V375= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV60439331; called by muse, mutect2, varscan2
- ABCB5 | c.1707+400G>A | Intron (SNP) | VAF 46/190 reads (24%) | catalogued as rs1562544766, COSV51703991; called by muse, mutect2, varscan2
- AC073310.1 | n.892A>T | RNA (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- ASB11 | c.181+1037T>C | Intron (SNP) | VAF 26/137 reads (19%) | catalogued as COSV60355684; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+72C>T | Intron (SNP) | VAF 46/185 reads (25%) | catalogued as COSV51469181; called by muse, mutect2, varscan2
- CLN5 | c.*121G>C | 3'UTR (SNP) | VAF 18/56 reads (32%) | catalogued as COSV62918976; called by muse, mutect2, varscan2
- EI24P4 | n.966T>C | RNA (SNP) | VAF 61/234 reads (26%) | called by muse, mutect2, varscan2
- GATAD2A | c.-46G>T | 5'UTR (SNP) | VAF 19/59 reads (32%) | catalogued as COSV53072310; called by muse, mutect2, varscan2
- MAP4 | c.1999+5769G>C | Intron (SNP) | VAF 50/270 reads (19%) | catalogued as COSV53139496; called by muse, mutect2, varscan2
- NCAM1 | c.1826-5536T>G | Intron (SNP) | VAF 26/108 reads (24%) | catalogued as rs368265862; called by muse, mutect2, varscan2
- PRRC2B | c.6226-859G>T | Intron (SNP) | VAF 32/128 reads (25%) | catalogued as COSV100260810; called by muse, mutect2, varscan2
- SFRP1 | c.*1T>G | 3'UTR (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99616806; called by muse, mutect2, varscan2
- SNORD115-35 | n.3del | RNA (DEL) | VAF 46/197 reads (23%) | called by mutect2, pindel, varscan2
- WASF4P | n.666T>G | RNA (SNP) | VAF 16/85 reads (19%) | called by muse, mutect2, varscan2
